Somatic mutation profile of tumor specimen TARGET-10-PARBIX-03A (aliquot TARGET-10-PARBIX-03A-01D) from TARGET case TARGET-10-PARBIX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (811 days).
Specimen TARGET-10-PARBIX-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d583f519-4a0a-4b4a-b381-a6f00f390e7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBIX-10A (Blood Derived Normal), aliquot TARGET-10-PARBIX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a647e3e-6eef-4e8e-a7cf-74cda11f235e

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Frame Shift Ins 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GP2 | c.740G>A p.G247D (on ENST00000381362 / NM_001007240.3; = p.G244D on NM_001502.4) | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs749502475; called by muse, mutect2
- NELL2 | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs200918496, COSV61569411; called by muse, mutect2, varscan2
- PRLH | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs770338709; called by muse, mutect2, varscan2
- VWC2L | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs371952173; called by muse, mutect2, varscan2
- ZMIZ1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.985); catalogued as COSV57892513; called by muse, mutect2, varscan2
- CATSPERG | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); called by muse, mutect2
- DAP | c.217_225delinsCC p.A73Pfs*145 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | called by pindel, varscan2*
- PPP2R2A | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SPTA1 | c.802_803insA p.R268Qfs*8 | Frame Shift Ins (INS) | VAF 30/96 reads (31%) | called by mutect2, pindel*, varscan2
- LEO1 | c.*60G>T | 3'UTR (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
